Somatic mutation profile of tumor specimen BA2125D (aliquot aq-BA2125D) from BEATAML1.0 case 2562, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.2 years (25,995 days).
Specimen BA2125D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f96e06e-8261-4caa-94ce-b3fd9471d82e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2713D (Solid Tissue Normal), aliquot aq-BA2713D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c1a70a-fabd-4960-ba95-d393a28731dc

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM47A | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.983); catalogued as rs759715180, COSV100649893; called by muse, mutect2, varscan2
- MAL2 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99411165; called by muse, mutect2
- ARHGAP28 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- CADPS | c.3125T>G p.M1042R | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CBFA2T3 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNJ12 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.125); called by muse, mutect2
- PARM1 | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- SORCS2 | c.3247G>A p.V1083I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPR | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NECTIN1 | c.1383C>T p.D461= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs140477415; called by muse, varscan2
